Gene-level copy-number profile of tumor specimen TCGA-02-0260-01A from TCGA case TCGA-02-0260, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.6 years (19,956 days).
Specimen TCGA-02-0260-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.6f003865-d544-441c-8b07-7dfb05559ba8.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,075 have no estimate.
https://portal.gdc.cancer.gov/files/1bad9612-1a65-4e7b-8df9-b3f10103df32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 2,200; copy number 2: 47,516; copy number 3: 5,289; copy number 4: 301; copy number 5: 151.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0260-01): tumor purity 0.92, ploidy 2.03, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–2): MLLT3.
- chr9:20,502,265–26,805,862, 90 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 151 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:56,087,366–58,362,848, 151 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
